Somatic mutation profile of tumor specimen TCGA-DZ-6133-01A (aliquot TCGA-DZ-6133-01A-11D-1961-08) from TCGA case TCGA-DZ-6133, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.6 years (24,311 days).
Specimen TCGA-DZ-6133-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b6171dc-19b8-418c-b1f7-3bb2d7b7857a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DZ-6133-10A (Blood Derived Normal), aliquot TCGA-DZ-6133-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e8779c0-945e-4726-b318-2d237b95301d

The open-access MAF lists 98 somatic variants for this specimen: 74 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 60, Silent 24, Frame Shift Del 6, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.1941G>T p.E647D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV64604038; called by muse, mutect2, varscan2
- AMER1 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs775489804, COSV100367031, COSV57663553; called by muse, mutect2, varscan2
- ANGPT2 | c.1382C>A p.P461Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as COSV57338567; called by muse, varscan2
- ANKK1 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV58272949; called by muse, mutect2
- APBA3 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100349583; called by muse, mutect2
- ATP13A3 | c.3263C>T p.A1088V | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV55467058; called by mutect2, varscan2
- CASC3 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV52868305; called by muse, mutect2, varscan2
- CCKAR | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV55162523, COSV99810591; called by muse, mutect2, varscan2
- CDC5L | c.1373A>T p.D458V | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV65176623; called by muse, varscan2
- CEMIP2 | c.3408C>A p.S1136R | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV65488234; called by muse, mutect2, varscan2
- CERK | c.429A>C p.K143N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53452336; called by muse, mutect2, varscan2
- CPEB3 | c.1987T>C p.C663R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56459592; called by muse, mutect2, varscan2
- CTDNEP1 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV56642422; called by muse, mutect2, varscan2
- EP400 | c.6127G>A p.A2043T | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV57778273; called by muse, mutect2, varscan2
- EP400 | c.6128C>T p.A2043V | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.292); catalogued as COSV57778287; called by muse, mutect2, varscan2
- EPB41L1 | c.2131A>G p.I711V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52440631; called by muse, mutect2, varscan2
- EPHA8 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs757672919, COSV51277855; called by mutect2, varscan2
- FABP12 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.4); catalogued as rs868486519, COSV64617388; called by muse, mutect2, varscan2
- FMNL3 | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV53304704; called by muse, mutect2
- HMG20A | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.775); catalogued as COSV60313362; called by muse, varscan2
- HSP90B1 | c.1517T>C p.L506P | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55356577; called by muse, mutect2, varscan2
- INTS2 | c.1306C>A p.L436I | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52154653; called by muse, mutect2, varscan2
- KBTBD6 | c.1742A>G p.N581S | Missense Mutation (SNP) | VAF 136/226 reads (60%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV65271608; called by muse, mutect2, varscan2
- KCNH1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV55090758; called by muse, varscan2
- KRT83 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV53341244; called by muse, mutect2, varscan2
- MMP24 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55771554; called by muse, mutect2, varscan2
- MPO | c.2092T>A p.S698T | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV51860546; called by mutect2, varscan2
- MYO1H | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs1432007382, COSV60447921, COSV60448086; called by muse, mutect2, varscan2
- NALCN | c.1020C>A p.S340R | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV51949001; called by muse, mutect2, varscan2
- NBEAL2 | c.7816G>A p.A2606T | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1214620419, COSV52760829; called by muse, mutect2, varscan2
- NCOR1 | c.161C>G p.S54* | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as COSV51970966, COSV51984385; called by muse, mutect2, varscan2
- NRIP1 | c.1570A>G p.N524D | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs149069507; called by muse, mutect2, varscan2
- OBSCN | c.11821G>A p.G3941S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52735481; called by muse, mutect2, varscan2
- PALM | c.368C>G p.P123R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as rs568795902, COSV99214674; called by mutect2, varscan2
- PAPPA | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60287533, COSV60292268; called by muse, mutect2, varscan2
- PCSK1 | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.834); catalogued as rs140941383; called by muse, mutect2, varscan2
- PEX5 | c.147+2T>C p.X49_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as COSV56956586; called by muse, varscan2
- PIP5K1C | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs771191741, COSV58954144; called by muse, mutect2, varscan2
- PLEKHA6 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV55336439; called by mutect2, varscan2
- PLEKHG1 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs138970683; called by mutect2, varscan2
- PSMD8 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV53057714; called by muse, mutect2, varscan2
- PTPRD | c.3426A>G p.I1142M | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV61962390; called by muse, mutect2, varscan2
- RRNAD1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs775649086, COSV63928805; called by muse, mutect2, varscan2
- SCUBE3 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51458521; called by muse, mutect2, varscan2
- SETD4 | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as COSV59772897; called by muse, mutect2, varscan2
- SFMBT1 | c.44T>C p.M15T | Missense Mutation (SNP) | VAF 117/200 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV56255474; called by muse, mutect2, varscan2
- SINHCAF | c.649T>G p.S217A | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV61797519; called by muse, mutect2, varscan2
- SIPA1L1 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62171772; called by muse, varscan2
- SIPA1L1 | c.1145T>A p.F382Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV62171778; called by muse, varscan2
- SLC6A18 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771860200, COSV57252783; called by mutect2, varscan2
- SP110 | c.582A>C p.S194= | Splice Region (SNP) | VAF 138/251 reads (55%) | catalogued as COSV51258702; called by muse, mutect2, varscan2
- SPATA17 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as rs768969404, COSV65119275, COSV65119631, COSV65124228; called by mutect2, varscan2
- SPATA31D1 | c.4097T>C p.I1366T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as rs1182512550, COSV61198423; called by muse, mutect2, varscan2
- SYNE1 | c.11753A>G p.E3918G | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54975445; called by muse, mutect2
- TGFA | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782074408, COSV54913414, COSV54913742; called by muse, mutect2, varscan2
- THBS1 | c.2834T>C p.I945T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs762216357, COSV52953903; called by muse, mutect2, varscan2
- TMEM167A | c.136T>C p.C46R | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs746223832, COSV71816124; called by muse, mutect2, varscan2
- TOPORS | c.2708G>C p.R903P | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV62117493; called by muse, mutect2, varscan2
- TSC2 | c.3577G>A p.G1193S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV54771586; called by muse, mutect2, varscan2
- TTN | c.49886T>C p.I16629T (on ENST00000591111; = p.I9205T on NM_003319.4) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | PolyPhen benign (0.109); catalogued as rs768963302, COSV60184906; called by muse, varscan2
- VARS2 | c.283+1G>A p.X95_splice | Splice Site (SNP) | VAF 45/87 reads (52%) | catalogued as COSV52559971; called by muse, mutect2, varscan2
- ZAN | c.2096C>A p.S699Y | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.867); catalogued as COSV61805337; called by mutect2, varscan2
- ZBTB11 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57245938, COSV57246056; called by muse, varscan2
- ZNF180 | c.1625C>G p.T542S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55422444; called by muse, mutect2, varscan2
- ZNF324B | c.592T>A p.C198S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100351785, COSV60742527; called by muse, varscan2
- CDK13 | c.2879del p.L960* | Frame Shift Del (DEL) | VAF 55/141 reads (39%) | called by mutect2, pindel, varscan2
- LENG8 | c.202_213+3del | In Frame Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel
- MMS22L | c.1506_1525del p.H502Qfs*17 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel
- RRP12 | c.3629del p.P1210Lfs*33 | Frame Shift Del (DEL) | VAF 35/83 reads (42%) | called by mutect2, pindel, varscan2
- SCN8A | c.2323del p.H775Ifs*3 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2433G>C p.K811N (on ENST00000621492; = p.K777N on NM_025248.3) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SRRM4 | c.701del p.P234Lfs*24 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- TMPO | c.1211del p.K404Rfs*12 | Frame Shift Del (DEL) | VAF 37/102 reads (36%) | called by mutect2, pindel, varscan2
- UBR4 | c.9846dup p.A3283Cfs*16 | Frame Shift Ins (INS) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- ANXA3 | c.498A>G p.E166= | Silent (SNP) | VAF 83/228 reads (36%) | catalogued as COSV53715632; called by muse, mutect2, varscan2
- ARID1B | c.5286G>A p.K1762= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV51670362; called by muse, mutect2, varscan2
- BIN3 | c.235C>T p.L79= | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as COSV52385511; called by muse, mutect2, varscan2
- GTF2H4 | c.363C>T p.A121= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as COSV52559961; called by muse, mutect2, varscan2
- HARBI1 | c.420G>T p.G140= | Silent (SNP) | VAF 69/196 reads (35%) | catalogued as COSV56320659; called by muse, mutect2, varscan2
- HLA-DQA2 | c.663C>T p.C221= | Silent (SNP) | VAF 66/139 reads (47%) | catalogued as rs572758897, COSV66565978; called by muse, mutect2, varscan2
- INSRR | c.456C>T p.T152= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV63875298; called by muse, mutect2, varscan2
- IPO8 | c.2523G>C p.L841= | Silent (SNP) | VAF 74/118 reads (63%) | catalogued as COSV56243437; called by muse, mutect2, varscan2
- MAP4K4 | c.2886C>A p.I962= (on ENST00000347699 / NM_001242559.2; = p.I880= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/83 reads (59%) | catalogued as COSV56335617; called by muse, mutect2, varscan2
- NCOR2 | c.2862T>C p.N954= | Silent (SNP) | VAF 75/140 reads (54%) | catalogued as COSV62300587; called by muse, mutect2, varscan2
- NICN1 | c.315G>C p.L105= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV56470268; called by muse, mutect2, varscan2
- PLRG1 | c.15A>G p.V5= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV57424141; called by muse, mutect2, varscan2
- PPP6R3 | c.2469T>A p.S823= (on ENST00000393800 / NM_001352375.2; = p.S743= on NM_018312.5) | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV55730851; called by muse, mutect2, varscan2
- PSMB4 | c.15G>A p.L5= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV51852325; called by muse, mutect2, varscan2
- REXO5 | c.1398C>T p.A466= | Silent (SNP) | VAF 277/441 reads (63%) | catalogued as COSV54473301; called by muse, mutect2, varscan2
- RPL37A | c.153T>A p.A51= | Silent (SNP) | VAF 80/154 reads (52%) | catalogued as COSV62897479; called by muse, mutect2, varscan2
- RSPH6A | c.456C>T p.Y152= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV55573585; called by muse, mutect2, varscan2
- SLCO2A1 | c.366C>G p.S122= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV60487329; called by muse, mutect2, varscan2
- TAS1R3 | c.1980G>A p.V660= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV59564365; called by muse, mutect2, varscan2
- TMEM120A | c.546C>A p.L182= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV58694548, COSV58695555; called by muse, mutect2, varscan2
- TRBC2 | c.105C>T p.G35= | Silent (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- UPP2 | c.300A>G p.R100= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV50048116; called by muse, mutect2, varscan2
- VCP | c.1314T>C p.D438= | Silent (SNP) | VAF 116/230 reads (50%) | catalogued as COSV62721306; called by muse, varscan2
- ZBTB49 | c.1854C>A p.S618= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV61925488; called by mutect2, varscan2
